Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A6U9, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A6U9-01A (Primary Tumor).

Neuropathology

Commentary:

Histology and morphology correspond to anaplastic astrocytoma WHO grade III.

Diagnosis:

Anaplastic astrocytoma WHO grade III

C6CF

ICD-O-3

Astrocytoma, grade III
path 9401/3

Astrocytoma, anaplastic 9401/3

Site: Brain, supratentorial NOS
C71.0

Sp 7/25/13

Untranslated original report
is housed at the BCR.

Source: NCI Genomic Data Commons file 4d0142ed-18b6-4f60-bcc8-aae1673a4dee (TCGA-S9-A6U9.3F2EBA7C-1491-4995-9AE4-CE0875950F1E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).